Somatic mutation profile of tumor specimen ALCH-B27Y-TTP1-A (aliquot ALCH-B27Y-TTP1-A-1-0-D-A775-36) from ALCHEMIST case ALCH-B27Y, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.7 years (21,066 days).
Specimen ALCH-B27Y-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26de8f2f-9620-40fa-87f6-8e0eb4c74c8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B27Y-NB1-A (Blood Derived Normal), aliquot ALCH-B27Y-NB1-A-1-0-D-A775-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81aa3149-a089-4e37-84c1-637cda715bf5

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 8, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 91/609 reads (15%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- EXOC3 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as rs1437172275; called by mutect2, varscan2
- FAM161A | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 38/460 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201998260, COSV56764939; called by muse, mutect2
- FAT1 | c.9496G>T p.D3166Y | Missense Mutation (SNP) | VAF 17/310 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV71675451; called by muse, mutect2
- FEZF1 | c.68T>C p.M23T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs751530130; called by muse, mutect2
- OTOG | c.5545G>A p.A1849T | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.036); catalogued as rs1430190942; called by muse, mutect2, varscan2
- STX1B | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 7/188 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as rs1183707872, COSV52682107; called by muse, mutect2
- ZNF655 | c.295C>G p.L99V | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV53158950; called by muse, mutect2
- GSPT2 | c.295C>G p.P99A | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); called by muse, mutect2
- MGAT4B | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2
- NECAB1 | c.142T>G p.F48V | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); called by muse, mutect2
- NRDE2 | c.1312C>A p.H438N | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- PFKP | c.1718C>A p.T573N | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POLE | c.6586T>A p.S2196T | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- UPRT | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.112); called by muse, mutect2
- ABCA5 | c.393C>T p.F131= | Silent (SNP) | VAF 13/157 reads (8%) | called by muse, mutect2
- DOCK11 | c.666C>T p.Y222= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV99354349; called by muse, mutect2
- DOCK8 | c.4503G>A p.V1501= | Silent (SNP) | VAF 25/301 reads (8%) | called by muse, mutect2
- FAT3 | c.6156G>A p.L2052= | Silent (SNP) | VAF 36/400 reads (9%) | called by muse, mutect2
- HOXD13 | c.456G>A p.K152= | Silent (SNP) | VAF 16/498 reads (3%) | called by muse, mutect2
- LAMA2 | c.2034T>G p.L678= | Silent (SNP) | VAF 36/613 reads (6%) | catalogued as rs769577654; called by muse, mutect2
- NRDE2 | c.1087C>T p.L363= | Silent (SNP) | VAF 43/363 reads (12%) | called by muse, mutect2, varscan2
- PURG | c.480G>A p.S160= | Silent (SNP) | VAF 39/500 reads (8%) | catalogued as rs756150951; called by muse, mutect2
- UNC5A | c.721+668C>T | Intron (SNP) | VAF 9/75 reads (12%) | catalogued as rs934872240; called by muse, mutect2, varscan2
